TARGET case TARGET-00-RO02580 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/35319559-c0e5-4a20-bd4d-e716b4224a8a

Biospecimens (1 sample)
- Sample TARGET-00-RO02580-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
